Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3AU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3AU-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient Name: [REDACTED] Service: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Visit #: [REDACTED] Collected: [REDACTED]
DOB: [REDACTED] Location: [REDACTED] Received: [REDACTED]
Gender: [REDACTED] Facility: [REDACTED] Reported: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]
Copy To: [REDACTED]

Specimen(s) Received

1. Lymph-Node: Right Iliac, common
2. Lymph node: Left common iliac nodes
3. Lymph node: Left pelvic lymph node
4. Lymph node: Right pelvic lymph node
5. Uterus: Hysterectomy - uterus, cervix, tubes & ovaries
6. Lymph node: Pelvic node left number 2

Diagnosis

1. Lymph-Node: Right Iliac, common:
No lymph node present
Fibrofatty tissue
2. Lymph node: Left common iliac nodes:
No lymph node present
Fibrofatty tissue
3. Lymph node: Left pelvic lymph node:
Six nodes, negative for carcinoma (0/6)
4. Lymph node: Right pelvic lymph node:
One of five nodes, positive for carcinoma (1/5)
5. Uterus: Hysterectomy - uterus, cervix, tubes & ovaries:
ENDOMETRIAL CARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE III with minor undifferentiated component
Depth: Outer half of myometrium with extension into soft tissue at lower uterine segment but not to margin
Cervix: Positive for stromal invasion by carcinoma
Lymphovascular space invasion: positive
6. Lymph node: Pelvic node left number 2:
Three nodes, negative for carcinoma (0/3)

ICD-0-3
carcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1
hw 11/13/11

HI/PA Discrepancy		X

[page 2 of 4]
Surgical Pathology Consultation Report

Synoptic Data

Specimen: Uterine corpus
Cervix
Right ovary
Left ovary
Right fallopian tube
Left fallopian tube
Procedure: Simple hysterectomy
Bilateral salpingo-oophorectomy
Other (specify): nodes
Lymph Node Sampling: Performed: Pelvic lymph nodes
Performed: iliac
Specimen Integrity: Intact hysterectomy specimen
Tumor Site: Other: ant and post
Tumor Size: Greatest dimension: 4.5 cm
Histologic Type: Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade: FIGO grade 3
Myometrial Invasion: Present
Myometrial thickness: 18 mm
50% or greater myometrial invasion
Involvement of Cervix: Invasion of cervical stromal connective tissue
Extent of Involvement of Other Organs:
Right ovary not involved
Left ovary not involved
Right fallopian tube not involved
Left fallopian tube not involved
Lymph-Vascular Invasion: Present
TNM Descriptors: Not applicable
Primary Tumor (pT): pT2 (II): Tumor invades stromal connective tissue of the cervix, but does not extend beyond uterus
Regional Lymph Nodes (pN): pN1 (IIIC1): Regional lymph node metastasis to pelvic lymph nodes
Pelvic lymph nodes examined: 14
Pelvic lymph nodes involved: 1
Para-aortic lymph nodes examined: 0
Para-aortic lymph nodes involved: 0
Distant Metastasis (pM): Not applicable

Electronically verified by:

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph Node: Right iliac, common" consists of two fragments of tissue measuring 1.0 x 0.7 x 0.5 cm and 1.6 x 1.0 x 0.5 cm received in 10% buffered formalin.
1A- submitted in toto.
2. The specimen container is labeled with the patient's name and as "Lymph Node: Left common iliac nodes" consists of two fragments of soft tissue measuring 1.7 x 1.0 x 0.4 cm and 2.0 x 1.0 x 0.5 cm received in 10% buffered formalin.
2A2B-submitted in toto.
3. The specimen container is labeled with the patient's name and as "Lymph Node: Left pelvic lymph node" consists of a single piece of unoriented fatty tissue measuring 6.5 x 4.0 x 2.0 cm received in 10% buffered formalin. Within the fatty

[page 3 of 4]
Surgical Pathology Consultation Report

tissue, multiple lymph nodes are identified ranging in size from 1.0 cm to 4.4-cm. The specimen is submitted in toto as follows:

- 3A-3B- one lymph node bisected
- 3C-3D- one lymph node bisected
- 3E-3F- one lymph node serially sectioned
- 3G- one lymph node bisected
- 3H-3K- 2 nodes and remainder of fatty tissue.

4. The specimen container is labeled with the patient's name and as "Lymph Node: Right pelvic lymph node" consists of a piece of unoriented fatty tissue measuring 5.5 x 3.8 x 1.5 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified ranging in size from 0.7 cm to 3.0-cm. The specimen is submitted in toto as follows:

- 4A-4B- one lymph node bisected.
- 4C-4D- one lymph node bisected
- 4E- one lymph node bisected
- 4F- one lymph node bisected
- 4G-4J- one node and remainder of fatty tissue.

5. The specimen container is labeled with the patient's name and as "Uterus: Hysterectomy-uterus, cervix, tubes and ovaries" contains a uterus, cervix, bilateral fimbriated fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 8.4 cm SI x 0 cm ML x 4.4 cm AP and the cervix measures 2.0 cm. in diameter with a 0.6 cm os. The right and left fimbriated fallopian tube measure 2.3 cm in length and 0.3 cm in diameter and 3.0 cm in length and 0.4 cm in diameter respectively. The right and left ovaries measure 1.3 x 0.7 x 0.5 cm and 1.3 x 0.8 x 0.7 cm respectively. The entire specimen weighs 212 g. The cut surfaces of both right and left ovaries are solid in consistency with a yellow-tan to gray-tan appearance. Both fallopian tubes are fimbriated and otherwise grossly unremarkable. There is a polypoid mass occupying the anterior and posterior endometrium extending from upper to lower uterine segment near the cervix measuring 4.5 x 2.3 x 1.5 cm in depth going into the myometrium. There is a nodule on the ectocervix measuring 0.4 cm. The ectocervical and endocervical mucosa are congested with some nodular areas. A well-circumscribed nodule/fibroid is noted on the anterior mid lower myometrium measuring 2.0 cm. Representative sections are submitted as follows:

- 5A-5B- remainder of right ovary submitted in toto.
- 5C- remainder of right fallopian tube and right fimbria submitted in toto.
- 5D-5E- remainder of left ovary submitted in toto.
- 5F-5G- remainder of left fallopian tube and fimbria submitted in toto.
- 5H-5J- full transverse sections of the anterior endomyometrium with tumor
- 5K- longitudinal section of the anterior lower uterine segment with fibroid
- 5L-5M- anterior cervix
- 5N-5P- full transverse sections of the posterior endomyometrium
- 5Q- longitudinal section of the posterior lower uterine segment
- 5R-5S- posterior cervix
- 5T- posterior right lower uterine segment with adjacent soft tissue
- 5U- posterior left lower uterine segment with adjacent soft tissue.
- One piece of left fallopian tube, left ovary, right fallopian tube, right ovary, endometrial ca are stored frozen.

Additional blocks: at the time of gross examination multiple cysts are noted in the right paraovarian tissue the largest measuring 0.6 cm and containing partly clear fluid and partly gelatinous material.

- 5V-5AC remainder of query anterior endomyometrium submitted from superior to inferior (V, X-Y, section trisected)
- 5AD-5AF remainder of query posterior endomyometrium submitted from superior to inferior
- 5AG-5AH endomyometrium

6. The specimen container is labeled with the patient's name and as "Lymph Node: Pelvic node left number 2" consists of multiple pieces of fatty tissue measuring in aggregate 3.0 x 3.0 x 1.3 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 1.4 to 2.2 cm The specimen is submitted in toto as follows:

- 6A- one lymph node bisected
- 6B-6C- one lymph node bisected
- 6D- one lymph node bisected
- 6E- remainder of fatty tissue.

[page 4 of 4]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file 8a6628ff-0e17-45ff-b83e-2b3a97655a11 (TCGA-EO-A3AU.B1D13355-6346-4FA4-950A-84114901515C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).